TCGA case TCGA-27-2523 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Milan - Italy, Fondazione IRCCS Instituto Neuroligico C. Besta. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/737b35e1-d668-4fce-9b6e-76946c7952b6

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Dead; Days to death: 489 days (1.3 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 63.1 years (23,034 days); Year of diagnosis: 2005; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Dexamethasone; Treatment intent type: Adjuvant; Days to treatment start: -6 days; Days to treatment end: 489 days (1.3 years); Treatment dose: 3,960 mg; Prescribed dose: 8; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Phenytoin Sodium; Treatment intent type: Adjuvant; Days to treatment start: -6 days; Days to treatment end: 489 days (1.3 years); Treatment dose: 148,500 mg; Prescribed dose: 300; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 10 days; Days to treatment end: 59 days; Number of cycles: 2; Treatment dose: 315 mg; Prescribed dose: 90; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Treatment intent type: Adjuvant; Days to treatment start: 11 days; Days to treatment end: 11 days; Number of cycles: 1; Treatment dose: 160 mg; Prescribed dose: 160; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 29 days; Days to treatment end: 36 days; Treatment dose: 3,000 cGy; Number of fractions: 15; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 55 days; Days to treatment end: 60 days; Treatment dose: 3,000 cGy; Number of fractions: 15; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 60 days; Days to treatment end: 380 days (1.0 years); Number of cycles: 10; Treatment dose: 15,000 mg; Prescribed dose: 300; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Erlotinib; Treatment intent type: Adjuvant; Days to treatment start: 97 days; Days to treatment end: 386 days (1.1 years); Number of cycles: 10; Treatment dose: 1,500 mg; Prescribed dose: 150; Prescribed dose units: mg; Route of administration: Oral.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 64.2 years (23,436 days); Days to diagnosis: 402 days (1.1 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.

Follow-up (3 entries)
- Day 402 (post initial treatment): Progression or recurrence: Yes; Days to progression: 402 days (1.1 years).
- Days to follow up: 489 days (1.3 years); Disease response: With Tumor.
- Karnofsky performance status: 80; ECOG performance status: 1; Timepoint: Preoperative.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-27-2523-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.9; Intermediate dimension: 0.8; Shortest dimension: 0.3.
  Slide TCGA-27-2523-01A-01-BS1: Section location: Bottom; Percent tumor cells: 97; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 0.
  Slide TCGA-27-2523-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0.
- Sample TCGA-27-2523-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-27-2523-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2, Route of administrations: Route of administration: PO.
- Drug treatment 6: Pharmaceutical therapy drug name: Lumustine.

GDC annotations on this case (curator notes; quoted as recorded):
- Item may not meet study protocol: Pt treated with dexmethasone and phenytoin sodium 6 days prior to procurement. According to the NIH, dexmethasone is an ancillary or hormone drug; SEER lists phenytoin sodium as an anticonvulsant to treat seizures.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 489 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 489 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 402 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-27-2523-01A-01D-0784-01): tumor purity 0.92, ploidy 2.03, whole-genome doublings 0.
